Somatic mutation profile of cancer-model specimen HCM-CSHL-0073-C25-85B (3D Organoid; aliquot HCM-CSHL-0073-C25-85B-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0073-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 55.3 years (20,210 days).
Specimen HCM-CSHL-0073-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65d1d498-c31b-4439-98b0-275e327de9b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0073-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0073-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ca78920-58b2-4aa8-b6f4-4694093e2710

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, 3'UTR 2, In Frame Del 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 124/264 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAX6 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 143/283 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757259413, CM930572; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 141/141 reads (100%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- AJAP1 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs780059909, COSV65448666; called by muse, mutect2, varscan2
- AKAP13 | c.7801C>T p.R2601C (on ENST00000394518 / NM_007200.5; = p.R2605C on NM_006738.6) | Missense Mutation (SNP) | VAF 146/300 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs769750946; called by muse, mutect2, varscan2
- COMMD8 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 114/214 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.632); catalogued as rs1251858888; called by muse, mutect2, varscan2
- DMXL1 | c.2267A>G p.N756S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs932373218; called by muse, mutect2, varscan2
- DNAJC11 | c.44_49del p.Y15_Y16del | In Frame Del (DEL) | VAF 131/312 reads (42%) | catalogued as rs1364360929; called by mutect2, pindel, varscan2
- LDLR | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 224/457 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CD921042, CM970873; called by muse, mutect2, varscan2
- LYPD4 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs577217524; called by muse, mutect2, varscan2
- MYO9A | c.3727G>A p.G1243S | Missense Mutation (SNP) | VAF 96/188 reads (51%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.02); catalogued as rs1280359910, COSV61853685; called by muse, mutect2, varscan2
- NGF | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 143/268 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1400946002; called by muse, mutect2, varscan2
- OR10X1 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV63767721; called by muse, mutect2, varscan2
- SELENOP | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 77/180 reads (43%) | catalogued as COSV62794311; called by muse, mutect2, varscan2
- TRIM60 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV61971966; called by muse, mutect2, varscan2
- ABCD4 | c.1735C>G p.R579G | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- ANKRD30A | c.2033A>G p.K678R (on ENST00000611781; = p.K622R on NM_052997.2) | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- DISP2 | c.3385del p.H1129Tfs*172 | Frame Shift Del (DEL) | VAF 101/267 reads (38%) | called by mutect2, pindel, varscan2
- FCRL3 | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRPV1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 100/100 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZAN | c.8024G>C p.R2675P | Missense Mutation (SNP) | VAF 134/283 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- AJM1 | c.630C>T p.T210= | Silent (SNP) | VAF 84/192 reads (44%) | catalogued as rs760766323; called by muse, mutect2, varscan2
- C11orf95 | c.1938G>A p.A646= | Silent (SNP) | VAF 108/229 reads (47%) | called by muse, mutect2, varscan2
- FBN2 | c.4311C>T p.S1437= | Silent (SNP) | VAF 186/377 reads (49%) | catalogued as rs138665246; ClinVar: likely benign; called by muse, mutect2, varscan2
- INPP5D | c.2958C>T p.P986= (on ENST00000445964 / NM_001017915.3; = p.P985= on NM_005541.5) | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV100856861, COSV64038491; called by muse, varscan2
- PRAMEF15 | c.369C>T p.A123= | Silent (SNP) | VAF 198/453 reads (44%) | called by muse, mutect2, varscan2
- TMEM94 | c.631C>T p.L211= | Silent (SNP) | VAF 94/94 reads (100%) | called by muse, mutect2, varscan2
- VWF | c.8328G>T p.P2776= | Silent (SNP) | VAF 96/213 reads (45%) | catalogued as COSV54628556; called by muse, mutect2, varscan2
- KPNB1 | c.*32C>G | 3'UTR (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2
- MROH1 | c.*6C>T | 3'UTR (SNP) | VAF 19/539 reads (4%) | catalogued as rs1036296103; called by muse, mutect2
- PRSS40A | n.314C>G | RNA (SNP) | VAF 79/306 reads (26%) | called by muse, mutect2, varscan2
- TNFRSF12A | c.95-12C>T | Intron (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
